Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YI, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YI-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

yo who presents with episodes where she does not know where her left arm is, as well as fluttering of the left side of her face.

MRI: [REDACTED] There is a large predominantly T2 hyperintense mass, which involves the majority of the right posterior parietal lobe extending across the callosal splenium into the left parietal white matter as well as down to the subependymal surface of the right lateral ventricle atria and occipital horn. This mass demonstrates subtle heterogeneous enhancement along its anterior and lateral border. This enhancement was not well demonstrated on the outside MRI of the brain, which may be secondary to interval development versus technique. The mass is grossly measures 7 cm AP x 4.1 cm transverse (image 35 series 4). There is stable mild mass effect and effacement of the right lateral ventricle posteriorly. The exam is otherwise stable.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. A 1 x 0.2 x 0.1 cm aggregate of yellow-tan tissue is received. Representative has been previously submitted as frozen section AF1. The frozen section remnant is submitted in A1. The remaining nonfrozen tissue is submitted in A2.

B. "Brain tissue (BF1)", received fresh for frozen section. A 4.1 x 4 x 2 cm fragment of soft red tissue is received. Representative has been previously submitted as frozen section BF1. The frozen sections are submitted in B1, multiple additional sections are submitted in B2-B5.

/slides to

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioma

B. "Brain tissue": BF1- high-grade glioma

MICROSCOPIC EXAMINATION:

Microscopic examination demonstrates a highly cellular malignant glial neoplasm demonstrating marked nuclear pleomorphism and increased mitotic activity. Microvascular proliferation and pseudopalisading necrosis are not identified. In part B, subarachnoid accumulations of tumor cells are present.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

B. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

SUBARACHNOID ACCUMULATIONS OF TUMOR CELLS ARE PRESENT.

*ICD-O-3
Astrocytoma, anaplastic 9401/3
Site: Brain, supratentorial NOS
with Brain NOS C71.9
7/25/14*

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

[page 2 of 3]
Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (47% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (51% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

9p21 - LOSS (73% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (67% OF TUMOR CELLS EXHIBIT LOSS)

2 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING ANAPLASTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK B2).

LEUCOCYTE COMMON ANTIGEN (LCA): 10% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (15% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (10% OF TUMOR CELLS)

EGFR wt - NEGATIVE (2+ IN 2% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 40% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 20% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

[page 3 of 3]
Performed by: SURGICAL PATHOLOGY

Ordering MD:

Diagnostic Discrepancy		✓

Source: NCI Genomic Data Commons file e3c93877-4eb5-4bb9-94c4-f22f54e7ed66 (TCGA-E1-A7YI.17841D2A-99A8-4F1D-900B-70F6324591DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).